HCMI case HCM-BROD-1117-C56 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Ovary. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a8856f5a-594e-4ce6-86f2-4ddc5ec46df5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1949; Vital status: Dead; Days to death: 310 days; Cause of death: Cancer Related.

Diagnoses (2)
1. Mullerian mixed tumor (the primary disease): ICD-O-3 morphology code: 8950/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Classification of tumor: primary; Age at diagnosis: 66.5 years (24,306 days); AJCC staging edition: 7th; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Prior treatment: No; Sites of involvement: Omentum.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 20 days; Days to treatment end: 156 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 268 days; Days to treatment end: 287 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Mullerian mixed tumor: ICD-O-3 morphology code: 8950/6; ICD-10 code: C78.6; Tissue or organ of origin: Ovary; Site of resection or biopsy: Specified parts of peritoneum; Classification of tumor: metastasis; Age at diagnosis: 66.5 years (24,306 days); Peritoneal fluid cytological status: Malignant; Sites of involvement: Omentum.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 1.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Specified parts of peritoneum; Days to progression: 0 days.
- Days to follow up: 310 days; Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- CA-125: 284.
- CDKN2A (IHC): Positive.
- PAX8 (IHC): Positive.
- TP53 (IHC): Overexpressed.

Other clinical attributes
- Day 0: Risk factors: Endosalpingiosis.
- Timepoint category: Initial Diagnosis; Weight: 73 kg; Height: 170 cm; BMI: 25.3.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (1 sample)
- Sample HCM-BROD-1117-C56-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 14.
